Somatic mutation profile of tumor specimen ALCH-ADNI-TTP1-A (aliquot ALCH-ADNI-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADNI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.9 years (17,508 days).
Specimen ALCH-ADNI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 015bbae5-3f4c-4d4e-94bb-2935bd6c8bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADNI-NB1-A (Blood Derived Normal), aliquot ALCH-ADNI-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3527a1c7-0f27-4544-844d-e664de28eff0

The open-access MAF lists 42 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Nonsense Mutation 3, 3'UTR 2, Intron 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/726 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- CDKL5 | c.1729A>G p.M577V | Missense Mutation (SNP) | VAF 26/623 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1371786498; called by muse, mutect2
- FCRL4 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 21/559 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as COSV54859745; called by muse, mutect2
- IL1R1 | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 14/404 reads (3%) | catalogued as COSV99292846; called by muse, mutect2
- INSL4 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53328921; called by muse, mutect2
- KRTAP13-1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100819824, COSV62663162; called by muse, mutect2
- PLPPR4 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV64566817; called by muse, mutect2
- STRA6 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1466287209, COSV100121051; called by muse, mutect2
- UNC80 | c.8254C>T p.R2752W | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs371893801; called by muse, mutect2
- ADAMTS20 | c.5714T>A p.L1905H | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGB | c.4698G>T p.K1566N | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- B4GALNT2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47C | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLG2 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 28/762 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2
- GIT1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HERC2 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2
- HSPD1 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 28/920 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.172); called by muse, mutect2
- IRAK1 | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ITIH6 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2
- SEMA4A | c.811-3C>T | Splice Region (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- SETD2 | c.5230A>T p.R1744* | Nonsense Mutation (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- SLC5A4 | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2
- SLITRK2 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.051); called by muse, mutect2
- TIMM29 | c.372C>G p.Y124* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- TSHZ2 | c.2356C>A p.P786T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- AKT3 | c.1425A>C p.A475= | Silent (SNP) | VAF 28/434 reads (6%) | catalogued as COSV55629762; called by muse, mutect2
- CFAP46 | c.5550C>T p.V1850= | Silent (SNP) | VAF 22/388 reads (6%) | called by muse, mutect2
- CNTNAP5 | c.2922G>C p.V974= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as COSV70498164; called by muse, mutect2, varscan2
- DPP9 | c.1734C>T p.S578= (on ENST00000598800; = p.S607= on NM_139159.5) | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1180316828; called by muse, mutect2
- ITIH6 | c.45C>T p.T15= | Silent (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- KCNRG | c.666C>T p.G222= | Silent (SNP) | VAF 32/568 reads (6%) | called by muse, mutect2
- LPCAT3 | c.1419C>T p.H473= | Silent (SNP) | VAF 18/419 reads (4%) | called by muse, mutect2
- PIK3R6 | c.1800C>T p.S600= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as rs1375667139; called by muse, mutect2
- SCTR | c.492C>G p.L164= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as COSV50030612; called by muse, mutect2
- SLC18A2 | c.865C>T p.L289= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SPTBN1 | c.1269C>T p.L423= | Silent (SNP) | VAF 17/302 reads (6%) | catalogued as rs945044593, COSV61685698; called by muse, mutect2
- TAS1R2 | c.87G>C p.L29= | Silent (SNP) | VAF 18/549 reads (3%) | called by muse, mutect2
- ATF3 | c.349-210G>A | Intron (SNP) | VAF 35/544 reads (6%) | catalogued as rs555908176, COSV100421926; called by muse, mutect2
- CDKL5 | c.*51G>A | 3'UTR (SNP) | VAF 16/325 reads (5%) | called by muse, mutect2
- MIR296 | n.21C>T | RNA (SNP) | VAF 11/219 reads (5%) | called by muse, mutect2
- SPG7 | c.1531+17C>T | Intron (SNP) | VAF 31/446 reads (7%) | called by muse, mutect2
- SPTA1 | c.*10C>A | 3'UTR (SNP) | VAF 38/624 reads (6%) | called by muse, mutect2
